Somatic mutation profile of tumor specimen TCGA-Z4-A9VC-01A (aliquot TCGA-Z4-A9VC-01A-11D-A37C-09) from TCGA case TCGA-Z4-A9VC, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 37.2 years (13,576 days).
Specimen TCGA-Z4-A9VC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e3083a8f-b4c6-4b5c-9cb8-10f6ccceb7a4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-Z4-A9VC-10A (Blood Derived Normal), aliquot TCGA-Z4-A9VC-10A-01D-A37F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/30f607a2-5e52-4c21-9a9c-87a538727516

The open-access MAF lists 19 somatic variants for this specimen: 15 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 11, Silent 4, Frame Shift Ins 1, Splice Region 1, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3203dup p.N1068Kfs*5 | Frame Shift Ins (INS) | VAF 8/21 reads (38%) | catalogued as rs587776802; ClinVar: pathogenic; called by mutect2, varscan2
- PTEN | c.278A>C p.H93P | Missense Mutation (SNP) | VAF 19/57 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909238, CM051214, COSV100910602, COSV64296545, COSV64296755; ClinVar: uncertain significance; called by muse, varscan2
- PTEN | c.302T>C p.I101T | Missense Mutation (SNP) | VAF 17/62 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1339631701, CD110165, CM110135, CX983284, COSV64289692, COSV64297668, COSV64311547; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- DDC | c.1340G>A p.R447H | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767329849, CM077527, COSV63563400; called by muse, mutect2, varscan2
- FAM107B | c.424C>G p.R142G | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.027); catalogued as COSV51678969, COSV99474231; called by muse, mutect2, varscan2
- GOLGA3 | c.3981C>T p.N1327= | Splice Region (SNP) | VAF 7/40 reads (18%) | catalogued as rs754465551, COSV99212244; called by muse, mutect2, varscan2
- LILRB1 | c.1154A>G p.Q385R (on ENST00000427581; = p.Q349R on NM_006669.6) | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT tolerated (0.71); PolyPhen benign (0.009); catalogued as COSV100207586; called by muse, mutect2, varscan2
- RFX3 | c.1625G>A p.C542Y | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV100175029; called by muse, mutect2
- SCAP | c.1418G>A p.R473H | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.176); catalogued as rs368653657; called by muse, mutect2, varscan2
- SHF | c.772C>T p.P258S | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV99334643; called by muse, mutect2, varscan2
- SYNE1 | c.13079C>T p.A4360V (on ENST00000367255 / NM_182961.4; = p.A4289V on NM_033071.3) | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.316); catalogued as COSV99572939; called by muse, mutect2, varscan2
- TMEM132D | c.1853A>G p.E618G | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.6); catalogued as COSV101242997; called by muse, mutect2, varscan2
- TNXB | c.8108G>A p.R2703H (on ENST00000647633; = p.R2456H on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.061); catalogued as rs866389765, COSV64476337; called by muse, mutect2, varscan2
- HHIPL1 | c.933_935del p.N312del | In Frame Del (DEL) | VAF 18/56 reads (32%) | called by mutect2, pindel, varscan2
- SYNE2 | c.6211del p.E2071Kfs*19 | Frame Shift Del (DEL) | VAF 14/50 reads (28%) | called by mutect2, pindel, varscan2
- CSMD3 | c.9816C>A p.T3272= (on ENST00000297405 / NM_001363185.1; = p.T3103= on NM_052900.3) | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as COSV99841509; called by muse, mutect2
- MUC16 | c.24873C>T p.S8291= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as rs748849343, COSV101200583; called by muse, mutect2, varscan2
- TMEM214 | c.978T>C p.F326= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as COSV99476451; called by muse, mutect2, varscan2
- ZNF213 | c.1272C>T p.T424= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as rs771446960, COSV101206016; called by muse, mutect2, varscan2
